Surgical pathology report (de-identified scan), TCGA case TCGA-32-1978, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1978-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Right brain tumor
2. Right brain tumor
3. Hippocampus

GBM
CONTROL

CLINICAL DIAGNOSIS:

Brain tumor

TCGA-32-1978

GROSS DESCRIPTION:

1. Received fresh for frozen section labeled with the patient's name and "brain tumor" is a 1.0 x 0.7 x 0.2 cm semi solid red-tan soft tissue fragment. A smear is performed with the remainder frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

The specimen is subsequently entirely resubmitted in one cassette.

2. Received in formalin labeled with the patient's name and "right brain tumor" are multiple pink-tan hemorrhagic and necrotic soft tissue fragments measuring in aggregate size 3.5 x 3.0 x 1.0 cm. Representative sections (approximately 50%) are submitted in two cassettes.

3. Received in formalin labeled with the patient's name and "hippocampus" is a 1.4 x 0.6 x 0.5 cm pink-tan portion of soft tissue consistent with brain. The possible cortical surface is identified, with the specimen being serially sectioned perpendicular to this surface and entirely submitted in one cassette.

MICROSCOPIC DESCRIPTION:

- 1, 2. Sections demonstrate a markedly hypercellular glial neoplasm, the cells of which resemble small fibrillary astrocytes. Scattered mitotic figures are seen. Microvascular proliferation is prominent and there are large areas of tumor necrosis including pseudopalisading tumor necrosis. The tumor diffusely infiltrates the parenchyma.

3. Sections of hippocampus demonstrate a limited degree of invasion by glioblastoma as previously described. Nonspecific reactive changes are also seen. Ammon's horn sclerosis is not noted.

DIAGNOSIS:

- 1, 2. RIGHT BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA, WHO GRADE IV.

3. HIPPOCAMPUS, RESECTION:
HIPPOCAMPUS WITH FOCAL INVASION BY GLIOBLASTOMA.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

More than 10% of the cells are immunoreactive for MGMT. However, most are endothelial cells. There are patchy areas with definite nuclear positivity seen in tumor cells. Overall, this specimen consists of more than 75% cellular tumor and the tumor is considered positive for MGMT expression.

ADDENDUM DIAGNOSIS:

- 1, 2. RIGHT BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA, WHO GRADE IV.
- TUMOR CELLS POSITIVE FOR MGMT EXPRESSION.

Source: NCI Genomic Data Commons file fc715080-38d8-40c2-85a0-fd99ca949b5d (TCGA-32-1978.EAE7FCC4-D235-4F95-8D55-5F6EA5371929.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).